MMRF case MMRF_1099 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ad34b217-0e49-4f18-9084-c07473461644

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Dead; Days to death: 668 days (1.8 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.0 years (25,563 days); ISS stage: II; Days to last known disease status: 668 days (1.8 years); Days to last follow up: 668 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 4 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 285 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 136 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 144 days; Days to treatment end: 285 days.
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 333 days; Days to treatment end: 588 days (1.6 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 668.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 1): M Protein 3.91 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.599 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 580 mg/dL; Immunoglobulin G 37.6 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 3.3 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 9.5 g/dL; Glucose 7.59 mmol/L.
- Day 88 (ECOG 0): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 558 mg/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.13 mmol/L; Albumin 31 g/L; Total Protein 6.7 g/dL; Glucose 5.34 mmol/L.
- Day 176 (ECOG 0): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 392 mg/dL; Immunoglobulin G 16.8 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.15 mmol/L; Albumin 33 g/L; Total Protein 6.6 g/dL; Glucose 4.68 mmol/L.
- Day 265 (ECOG 0): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 414 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 6.8 g/dL; Glucose 5.34 mmol/L.
- Day 393 (ECOG 1): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 275 mg/dL; Immunoglobulin G 15.6 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 1.9 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 364 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.15 mmol/L; Albumin 33 g/L; Total Protein 6.4 g/dL; Glucose 4.95 mmol/L.
- Day 449 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 239 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 1.39 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 279 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 6.4 g/dL; Glucose 5.28 mmol/L.
- Day 540 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 299 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 1.53 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 393 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.15 mmol/L; Albumin 27 g/L; Total Protein 6.3 g/dL; Glucose 8.09 mmol/L.
- Day 596 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 261 mg/dL; Immunoglobulin G 14.5 g/L; Immunoglobulin A 1.83 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 349 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 27 g/L; Total Protein 6.5 g/dL; Glucose 5.56 mmol/L.

Other clinical attributes
- Day -3: Weight: 83 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1099_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1099_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
